Surgical pathology report (de-identified scan), TCGA case TCGA-IS-A3K8, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-IS-A3K8-01A (Primary Tumor).

[page 1 of 2]
Specimens Submitted:

- 1: SP: Endocervical polyp (fs)
- 2: SP: Endometrial curettings (fs)
- 3: SP: Cervical bx (fs)
- 4: SP: Uterine mass, portion of small bowel (fs)
- 5: SP: Uterus cervix
- 6: SP: Lt. fallopian tube ovary
- 7: SP: Rt. fallopian tube ovary

DIAGNOSIS:

- 1) ENDOCERVIX, POLYP, BIOPSY:
- BENIGN ENDOCERVICAL POLYP.
- 2) ENDOMETRIUM, CURETTAGE:
- SIMPLE HYPERPLASIA WITHOUT ATYPIA IN A BACKGROUND OF DISORDERED PROLIFERATIVE ENDOMETRIUM. ENDOMETRIAL POLYP.
- 3) CERVIX, BIOPSY:
- BENIGN CERVICAL TISSUE WITH NABOTHIAN CYSTS.
- 4) UTERINE MASS AND SEGMENT OF SMALL BOWEL, RESECTION:
- SMOOTH MUSCLE NEOPLASM WITH EPITHELIOID AND MYXOID FEATURES, MOST CONSISTENT WITH LEIOMYOSARCOMA, 20 CM IN GREATEST DIMENSION (SEE NOTE).
- TUMOR INFILTRATES INTO THE SUBSEROZA OF THE SMALL BOWEL.
- NEGATIVE BOWEL MARGINS OF RESECTION.
- NO VASCULAR INVASION SEEN.

NOTE: THE TUMOR SHOWS MODERATE CELLULARITY WITH AN AVERAGE OF 5 MITOSES/10 HIGH POWER FIELDS (RANGE 2-8). THERE IS NO NUCLEAR PLEOMORPHISM OR NECROSIS. OF INTEREST IS THE VASCULAR PATTERN, WHICH IS MORE COMMONLY SEEN IN STROMAL TUMORS THAN IN SMOOTH MUSCLE TUMORS. CLINICALLY, THE TUMOR APPEARS INCOMPATIBLE WITH A BENIGN LESION, PER REPORT. HISTOLOGICALLY, THE NEOPLASM APPEARS LOW GRADE AND JUST BARELY QUALIFIES FOR A MALIGNANCY BASED ON DATA PUBLISHED IN ABSTRACT FORM (SEE BELOW). THIS ABSTRACT REPORTS ONE METASTASIS AMONG 15 TUMORS WITH HISTOLOGIC FEATURES SIMILAR TO THIS CASE. THE IMMUNOPHENOTYPE SUPPORTS SMOOTH MUSCLE DIFFERENTIATION.

PATH
REPORT
11

** Continued on next page **

ICD-O-3 8891/3 8896/3
leiomyosarcoma, epithelioid and myxoid - code to highest
Site: uterus, NOS C55.9 1/1/12

[page 2 of 2]
REFERENCE: MOD PATHOL,
NUMBER 771.

VOL 14, PAGE 132A, ABSTRACT

- 5) UTERUS AND CERVIX, HYSTERECTOMY:
- LEIOMYOMATA, SUBSEROSAL, INTRAMURAL AND SUBMUCOSAL, UP TO
3.5 CM IN GREATEST DIMENSION.
- DISORDERED PROLIFERATIVE ENDOMETRIUM (SEE PART 2).
- BENIGN ENDOMETRIAL POLYP.
- BENIGN CERVIX.
- 6) OVARY AND FALLOPIAN TUBE, LEFT, SALPINGO-OOPHORECTOMY:
- BENIGN OVARY WITH FOLLICULAR CYSTS.
- UNREMARKABLE FALLOPIAN TUBE.
- PARATUBAL CYST.
- 7) OVARY AND FALLOPIAN TUBE, RIGHT, SALPINGO-OOPHORECTOMY:
- BENIGN OVARY WITH FOLLICULAR CYSTS AND INCLUSION CYSTS.
UNREMARKABLE FALLOPIAN TUBE.

** Report Electronically Signed Out **

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION
OF THE SLIDES (AND/OR OTHER
MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Source: NCI Genomic Data Commons file cbabfa7e-c742-4932-a38b-ca9a55f578a6 (TCGA-IS-A3K8.809A4E6C-C4DC-4BBD-B172-D7CAB0563E7A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).